Gene-level copy-number profile of tumor specimen TCGA-N5-A4RA-01A from TCGA case TCGA-N5-A4RA, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IIIC2; Age at diagnosis: 64.0 years (23,359 days).
Specimen TCGA-N5-A4RA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.8e2cafa4-4989-4f86-a0d7-c9b4058a142e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N5-A4RA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eced7723-7d34-4449-9edc-acf98225d330

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 379; copy number 2: 23,806; copy number 3: 18,622; copy number 4: 12,495; copy number 5: 3,037; copy number 6: 819; copy number 7: 182; copy number 8: 177; copy number 9: 9; copy number 10: 27; copy number 12: 22; copy number 28: 183; copy number 29: 50; copy number 33: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N5-A4RA-01A-11D-A28Q-01): tumor purity 0.82, ploidy 2.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:37,162,616–37,163,139, 1 gene: AC244093.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,509 genes in 60 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–6,730,012, 255 genes, copy number 5 (broad region; genes not listed).
- chr1:28,369,582–28,719,353, 24 genes, copy number 6 (within-gene range 3–6): PHACTR4, Y_RNA, CR391992.1, RNU6ATAC27P, RCC1, SNHG3, SNORA73A, SNORA73B, PRDX3P2, AL513497.1, TRNAU1AP, SNHG12, SNORD99, SNORA61, SNORA44, SNORA16A, SNORA16A, TAF12, RAB42, LINC01715, AL360012.1, RNU11, GMEB1, AL645729.1.
- chr1:37,133,489–40,450,039, 110 genes, copy number 5–6 (broad region; genes not listed).
- chr1:46,370,586–46,719,146, 15 genes, copy number 5: AL122001.1, FAAH, FAAHP1, LINC01398, DMBX1, TMEM275, MKNK1-AS1, KNCN, MKNK1, MOB3C, ATPAF1, NENFP1, TEX38, EFCAB14-AS1, EFCAB14.
- chr1:108,927,361–109,632,053, 33 genes, copy number 6: CLCC1, WDR47, BX679664.2, BX679664.3, BX679664.1, RANP5, TAF13, AL356488.3, TMEM167B, SCARNA2, AL356488.2, AL356488.1, C1orf194, ELAPOR1, SARS1, CELSR2, PSRC1, MYBPHL, SORT1, PSMA5, SYPL2, ATXN7L2, CYB561D1, AMIGO1, GPR61, AL355310.3, GNAI3, RNU6V, AL355310.1, MIR197, GNAT2, AMPD2, AL355310.2.
- chr1:143,343,180–155,563,162, 558 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:201,888,680–202,341,980, 21 genes, copy number 6: SHISA4, AL513217.1, LMOD1, TIMM17A, SNORA70H, RPL10P4, RNPEP, ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1, AL691482.2, Y_RNA, CRIP1P3, GPR37L1, ARL8A, PTPN7, PTPRVP, LGR6, UBE2T.
- chr2:32,521,927–32,926,693, 9 genes, copy number 5 (within-gene range 3–5): AL133243.2, AL133243.3, MIR558, AL133243.1, BIRC6-AS2, AL133243.4, TTC27, MIR4765, LINC00486.
- chr2:113,157,325–190,371,665, 1,100 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr2:216,351,403–216,695,549, 11 genes, copy number 8: Y_RNA, SMARCAL1-AS1, SMARCAL1, RPL37A-DT, AC098820.1, RPL37A, LINC01280, AC073321.1, PSMB3P2, IGFBP2, IGFBP5.
- chr2:221,944,223–223,198,399, 22 genes, copy number 12 (within-gene range 4–12): LLPHP3, HSPA9P1, RPL23AP28, PAX3, CCDC140, AC010980.1, CT75, Y_RNA, SGPP2, NANOGP2, RNU6-619P, GAPDHP49, FARSB, MOGAT1, RRAS2P2, AC104772.1, RPL31P17, ACSL3, ATG12P2, ACSL3-AS1, AC013476.1, KCNE4.
- chr3:13,316,235–13,937,477, 10 genes, copy number 5: NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2, LINC00620, WNT7A, VN1R20P, FGD5P1.
- chr3:49,940,007–51,384,198, 45 genes, copy number 5 (within-gene range 2–5): RBM6, RBM5, RBM5-AS1, SEMA3F-AS1, SEMA3F, AC104450.1, GNAT1, SLC38A3, GNAI2, MIR5787, U73169.1, U73166.1, SEMA3B-AS1, SEMA3B, MIR6872, LSMEM2, IFRD2, HYAL3, NAA80, HYAL1, HYAL2, TUSC2, RASSF1, RASSF1-AS1, ZMYND10-AS1, ZMYND10, NPRL2, CYB561D2, Z84492.2, TMEM115, CACNA2D2, Z84492.1, RNA5SP131, C3orf18, HEMK1, AC096920.1, CISH, MAPKAPK3, LINC02019, DOCK3, MIR4787, PPIAP69, AC126120.1, ZNF652P1, ST13P14.
- chr3:91,356,755–96,814,407, 29 genes, copy number 5: ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1.
- chr3:106,367,979–107,240,671, 19 genes, copy number 7 (within-gene range 4–7): AC079382.2, LINC00882, Y_RNA, AC080097.1, Y_RNA, FCF1P3, MTND4P16, MTND4LP3, MTND3P6, MTCO3P35, MTATP6P22, MTND5P16, MTND6P6, MTCO1P35, MTND1P16, MTND2P14, RNU6-1308P, AC117435.1, AC074043.1.
- chr3:168,858,659–170,181,749, 34 genes, copy number 7: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P.
- chr3:171,600,404–198,222,513, 531 genes, copy number 5–7 (broad region; genes not listed).
- chr4:1,402,932–2,069,089, 17 genes, copy number 5: NKX1-1, AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L.
- chr5:35,617,844–36,725,195, 25 genes, copy number 6: SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3.
- chr6:134,169,246–135,813,990, 33 genes, copy number 6 (within-gene range 4–6): SGK1, RPS29P32, RNA5SP218, Y_RNA, AL355881.1, KRT8P42, LINC01010, Z84486.1, CHCHD2P4, CT69, AL078590.2, FAM8A6P, AL078590.1, AL596188.1, AL121970.1, MEMO1P2, ALDH8A1, AL445190.1, HBS1L, MIR3662, AL353596.1, MYB, MYB-AS1, MIR548A2, AL023693.1, AHI1, AL049552.1, AL049552.2, Y_RNA, LINC00271, GAPDHP73, AL035604.1, HMGB1P17.
- chr6:151,196,681–152,129,619, 18 genes, copy number 8: AL138733.2, RNU6-300P, AL356535.1, AKAP12, RNU6-1247P, RNY4P20, RN7SKP268, ZBTB2, Y_RNA, RMND1, HSPA8P15, ARMT1, CCDC170, RNU6-813P, ESR1, AL356311.1, AL078582.2, AL078582.1.
- chr7:19,918,981–20,777,038, 14 genes, copy number 7 (within-gene range 3–7): AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1, EEF1A1P27, AC002486.2, ABCB5, AC002486.1.
- chr7:76,173,733–76,627,982, 17 genes, copy number 7: AC005077.3, SRRM3, HSPB1, YWHAG, PPIAP81, SSC4D, ZP3, DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16, AC004980.1, POMZP3.
- chr7:104,894,628–106,036,432, 23 genes, copy number 5 (within-gene range 4–5): LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P, PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1, CDHR3.
- chr8:27,311,482–28,191,156, 26 genes, copy number 6 (within-gene range 3–6): PTK2B, MIR6842, CHRNA2, EPHX2, GULOP, CLU, MIR6843, SCARA3, RNU6-1086P, AC013643.1, AC013643.3, MIR3622B, MIR3622A, AC013643.2, CCDC25, ESCO2, RNU6-1276P, PBK, AC104997.1, SCARA5, MIR4287, AC069113.1, AC069113.3, AC069113.2, NUGGC, ELP3.
- chr8:35,525,176–43,674,591, 190 genes, copy number 5 (broad region; genes not listed).
- chr8:47,260,878–60,142,142, 183 genes, copy number 28 (within-gene range 3–28) (broad region; genes not listed).
- chr8:68,695,643–72,118,393, 50 genes, copy number 29: RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1, EYA1, TRAPPC2P2, AC009446.1, AC104012.1, U8, MSC-AS1, MSC, RPS20P20, TRPA1.
- chr11:67,056,847–67,461,752, 25 genes, copy number 5: RHOD, KDM2A, AP001885.1, AP001885.3, GRK2, ANKRD13D, SSH3, AP001885.2, RAD9A, POLD4, AP003419.1, AP003419.2, RN7SKP239, CLCF1, AP003419.3, RNU6-1238P, PPP1CA, TBC1D10C, CARNS1, RPS6KB2, RPS6KB2-AS1, PTPRCAP, CORO1B, GPR152, CABP4.
- chr13:110,456,396–110,813,084, 9 genes, copy number 5: COL4A2-AS2, COL4A2-AS1, RAB20, AL139385.1, NAXD, CARS2, ING1, RPL21P107, LINC00567.
- chr14:22,123,318–22,613,215, 98 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr14:89,736,965–90,490,763, 16 genes, copy number 5 (within-gene range 4–5): CHORDC2P, EFCAB11, RAB42P1, TDP1, KCNK13, GLRXP2, Y_RNA, PSMC1, NRDE2, AL161662.1, RPL21P11, AL512791.2, CALM1, AL512791.1, LINC02317, LINC00642.
- chr15:62,823,957–63,594,640, 17 genes, copy number 5 (within-gene range 2–5): MIR190A, AC103740.1, AC103740.2, AC079328.1, TPM1, TPM1-AS, AC079328.2, AC087612.1, LACTB, RPS27L, RAB8B, APH1B, CA12, LINC02568, AC007950.1, AC007950.2, USP3.
- chr15:73,051,710–74,725,536, 54 genes, copy number 5: NEO1, FKBP1AP2, NPM1P43, AC068397.1, HCN4, AC068397.2, REC114, MRPS15P1, NPTN, NPTN-IT1, CD276, AC022188.1, INSYN1, INSYN1-AS1, AC018943.1, TBC1D21, LOXL1-AS1, LOXL1, STOML1, PML, AC013486.1, DNM1P33, GOLGA6A, RN7SL429P, COMMD4P2, ISLR2, AC010931.1, AC010931.2, Metazoa_SRP, ISLR, STRA6, CCDC33, AC023300.3, AC023300.1, AC023300.2, CYP11A1, PPIAP46, AC090826.1, AC090826.2, LINC02255, SEMA7A, MIR6881, AC090826.3, UBL7, UBL7-AS1, AC012435.2, AC012435.3, AC012435.1, ARID3B, CLK3, AC100835.2, AC100835.1, EDC3, CYP1A1.
- chr15:89,784,895–93,569,483, 115 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:47,694,081–48,908,983, 72 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:7,476,875–8,149,592, 50 genes, copy number 5 (within-gene range 3–5): PEX11G, TEX45, AC008878.1, ZNF358, AC008878.4, MCOLN1, AC008878.2, PNPLA6, CAMSAP3, MIR6792, XAB2, PET100, AC008763.2, PCP2, AC008763.1, STXBP2, RPS27AP19, RETN, MCEMP1, AC008763.3, TRAPPC5, FCER2, CLEC4G, AC008763.4, CD209, RPL21P129, CLEC4M, CLEC4GP1, EXOSC3P2, EVI5L, PRR36, AC010336.3, LYPLA2P2, 5S_rRNA, LRRC8E, AC010336.1, MAP2K7, AC010336.4, TGFBR3L, AC010336.2, SNAPC2, CTXN1, AC010336.5, TIMM44, AC010336.7, ELAVL1, AC010336.6, AC008946.1, CCL25, FBN3.
- chr19:27,638,483–40,690,972, 490 genes, copy number 6–8 (within-gene range 2–8) (broad region; genes not listed).
- chr20:31,605,283–32,003,387, 16 genes, copy number 5: ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2.
- chr20:35,433,029–35,950,370, 27 genes, copy number 6 (within-gene range 3–6): GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, U6, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P.

Autosomal genes at a single copy (total copy number 1): 34. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
